Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3IT, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3IT-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender: M

Ref. Physician:

Patient Address:

Location:

Service: Urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

INPATIENT

Ref. Source:

Clinical Diagnosis & History:

Patient with previous renal transplant on chronic immuno suppression, HGT2 bladder lesion, radical cystectomy and bilateral nephro-U.

Specimens Submitted:

- 1: Right ureter (fs)
- 2: Bladder, prostate and seminal vesicles, radical cystoprostatectomy
- 3: Left pelvic lymph nodes, resection
- 4: Left vas deferens
- 5: Left kidney
- 6: Portion of left adrenal gland
- 7: Right kidney

DIAGNOSIS:

1. Right ureter, biopsy (fs):

Benign segment of ureter

2. Bladder, prostate and seminal vesicles, radical cystoprostatectomy:

a.

Part # 2

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Flat (in situ carcinoma)

Focal

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Not identified

Bladder Local Invasion:

Perivesical soft tissues

Extravesical Tumor Extension:

Right ureter uninvolved

Urethra uninvolved

Invasive carcinoma is present in the region around the left ureteral orifice

Vascular Invasion:

Identified

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Exhibiting ulceration

ICD-O-3
carcinoma, urothelial, NOS 8120/3
Site: bladder, lateral wall c.c. 2

lw
12/7/11

HPV Discrepancy		X

lw 12/7/11

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Exhibiting foreign body reaction

Exhibiting proliferative cystitis (Brunn's nests, cystitis cystica, cystitis glandularis)

Prostate:

Other Please see Part B.

Seminal Vesicles:

Not involved

Perivesical Lymph Nodes:

Not identified

The Pathologic Stage is (AJCC 2002):

pT3 (Invasion of perivesicle soft tissue)

PR0 (No involvement of prostate)

b.

Part # 2

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:4

Total Gleason score:7

Tumor Location:

Involves Right anterior

Vascular Invasion:

Not Identified

Perineural Invasion:

Not identified

Tumor Multicentricity:

Not identified

High Grade Prostatic Intraepithelial Neoplasia:

Identified

Capsule:

Tumor confined to prostate

Seminal Vesicles:

Not involved

Bladder Neck:

Not Involved

Surgical Margins:

Free of tumor

Non-Neoplastic Prostate:

Exhibits nodular hyperplasia

Staging (AJCC 1997):

pT2a (confined to the prostate & capsule, involving one lobe)

3. Left pelvic lymph nodes, resection:

Part # 3

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 7

Number of lymph nodes with metastatic disease: 0

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Specimen entirely examined

4. Left vas deferens, resection:
Benign fibromuscular and vascular tissue
5. Left kidney, nephroureterectomy:
Histologic changes consistent with end-stage renal disease with diffuse glomerulosclerosis, extensive thyroidization and atrophy of tubules and interstitial chronic inflammation
Vasculature with diffuse concentric myointimal hyperplasia
Benign renal pelvic urothelial mucosa with proliferative changes
6. Portion of left adrenal gland, resection:
Benign adrenal gland
7. Right kidney, nephroureterectomy:
Histologic changes consistent with end-stage renal disease with diffuse glomerulosclerosis, extensive thyroidization and atrophy of tubules and interstitial chronic inflammation
Vasculature with diffuse concentric myointimal hyperplasia
Benign renal pelvic urothelial mucosa with proliferative changes

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "Right ureter" and consists of a segment of ureter measuring 1 x 0.5 cm. The specimen is bisected and entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

2). The specimen is received fresh, labeled "bladder, prostate, and seminal vesicles". It consists of a bladder with attached prostate and adnexa measuring 16.5 cm from superior to inferior, 10.5 cm laterally and 4.5 cm from anterior to posterior. The bladder measures 6.0 x 5.0 x 2.0 cm, the prostate measures 4.4 x 3.5 x 2.5 cm, the right seminal vesicle measures 3.4 x 2.0 x 0.9 cm, the right vas deferens measures 8.0 x 0.5 cm, the left seminal vesicle measures 3.2 x 1.8 x 0.9 cm and the left vas deferens measures 6.5 x 0.5 cm. The anterior aspect of the bladder is inked blue and the posterior black. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal an ulcerated lesion measuring 3.2 x 2.2 cm grossly situated within the left lateral wall. The lesion measures 1.5 cm from the left orifice and 3.5 from the right. Both ureters are probe patent measuring up to 0.2 cm in maximum diameter. The lesion is sectioned to reveal underlying fibrotic papillary tissue extending to a depth of 1.3 cm grossly approaching into the perivesicular fat. The remaining bladder mucosa is inked tan and otherwise grossly unremarkable. Discrete perivesical lymph nodes are not grossly identified. The prostate is serially sectioned to reveal diffuse tan-yellow nodularity. The entire prostate is submitted. is submitted. Representative sections are submitted.

Summary of sections:
UTHM - urethral margin
RUM - right ureter margin
LUM - left ureter margin
T - tumor

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

RUO - right ureter orifice
LUO - left ureter orifice
LP - left posterior wall
LA - left anterior wall
RP - right posterior wall
RA - right anterior wall
TRI - trigone
DOM - dome no cancer in a window of
F - perivesical fat
RSV - right seminal vesicle
LSV - left seminal vesicle
RAP - right apex prostate
LAP - left apex prostate
RAM - right anterior mid prostate
RPM - right posterior mid prostate
LAM - left anterior mid prostate
LPM - left posterior mid prostate
RAB - right anterior base prostate
RPB - right posterior base prostate
LAB - left anterior base prostate
LPB - left posterior base prostate
ADD – remainder of the prostate

3). The specimen is received in formalin, labeled "left pelvic lymph nodes", and consists of multiple pink tan firm lymph nodes ranging from 0.5 cm to 3 cm in greatest dimension. The entire specimen including all identifiable lymph nodes is submitted.

Summary of sections:

LN - lymph nodes
ADD – remainder of the specimen

4) the specimen is received in formalin labeled "left vas deferens", and consists of a 6.5 cm in length, 0.5 cm diameter tubular soft tissue. Representative sections are submitted.

Summary of sections:

R - representative

5). The specimen is received fresh, labeled "left kidney", and consists of a kidney with attached ureter, renal vessels, and perinephric fat. The kidney weighs 76.5 g. The kidney measures 10 x 4 x 3 cm. The attached ureter measures 23 cm in length and 0.5 cm in diameter. The attached renal vein measures 0.2 cm in length and 1 cm in diameter. The renal vessels and ureter are grossly unremarkable. The adrenal gland is not identified. The kidney is bivalved to reveal focal hemorrhagic pelvic mucosa and diffuse fatty infiltration in the renal parenchyma. Sections through the remainder of the kidney reveal thin cortex measuring 0.4 cm in thickness and pink brown parenchyma. No lymph nodes identified in the perinephric fat. Representative sections are submitted for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins
P -- Renal pelvis, representative sections
K -- Representative sections

6) the specimen is received in formalin labeled "portion of left adrenal gland", and consists of golden yellow glandular soft tissue in aggregate measuring 3 x 1.8 x 1.5 cm. There is a moderate amount of the fat tissue attached to it. Representative sections are submitted.

Summary of sections:

R – representative sections

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

7) The specimen is received fresh labeled "right kidney" and consists of a kidney with attached ureter, renal vessels, and perinephric fat weighing 550 g in total. The kidney weighs 71 g and measures 9 x 4.5 x 2.5 cm. The attached ureter measures 16 cm in length and 0.3 cm in diameter. The attached renal vein measures 0.8 cm in length and 0.6 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is bivalved to reveal tan-pink atrophic renal parenchyma with cortex measuring 0.6 cm in thickness. 80% of the renal parenchyma is replaced by fat. The cortico-medullary junction is not well-defined. The calyces appear atrophic. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins

P -- renal pelvis representative sections

K -- representative sections kidney

Summary of Sections:

Part 1: Right ureter (fs)

Block	Sect. Site	PCs
1	FSC	0

Part 2: Bladder, prostate and seminal vesicles, radical cystoprostatectomy

Block	Sect. Site	PCs
15	ADD	15
1	DOM	1
1	F	1
1	LA	1
1	LAB	1
1	LAM	1
1	LAP	1
1	LP	1
1	LPB	1
1	LPM	1
1	LSV	1
1	LUM	1
1	LUO	1
1	RA	1
1	RAB	1
1	RAM	1
1	RAP	1
1	RP	1
1	RPB	1
1	RPM	1
1	RSV	1
1	RUM	1
1	RUO	1
5	T	5
1	TRI	1
1	UTHM	1

Part 3: Left pelvic lymph nodes, resection

Block	Sect. Site	PCs
8	ADD	8
1	LN	0
2	LN1	0

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Part 4: Left vas deferens

Block	Sect. Site	PCs
1	R	2

Part 5: Left kidney

Block	Sect. Site	PCs
2	K	0
1	P	0
1	UVM	0

Part 6: Portion of left adrenal gland

Block	Sect. Site	PCs
1	R	2

Part 7: Right kidney

Block	Sect. Site	PCs
3	K	4
1	P	2
1	UVM	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Right ureter (fs): Benign
Permanent diagnosis: Same

Source: NCI Genomic Data Commons file 4729c3d0-8aed-4169-8737-31aafed89927 (TCGA-DK-A3IT.B42C9A76-53B5-46A6-833F-5A63871F92A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).